Somatic mutation profile of tumor specimen TCGA-AN-A0FV-01A (aliquot TCGA-AN-A0FV-01A-11W-A019-09) from TCGA case TCGA-AN-A0FV, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 58.8 years (21,479 days).
Specimen TCGA-AN-A0FV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9bcaccdb-2373-449b-bbc0-8280de732b63.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AN-A0FV-10A (Blood Derived Normal), aliquot TCGA-AN-A0FV-10A-01W-A021-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f8e8a3f0-60a1-410d-a912-aa98704cd490

The open-access MAF lists 93 somatic variants for this specimen: 68 protein-altering or splice-affecting, 23 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 23, Nonsense Mutation 4, Frame Shift Del 3, 5'Flank 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.755T>C p.L252P | Missense Mutation (SNP) | VAF 64/118 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912653, CM900212, COSV52764738, COSV52950153; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABR | c.370G>A p.A124T (on ENST00000302538 / NM_021962.5; = p.A87T on NM_001092.5) | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs1274518801, COSV52141619; called by muse, mutect2, varscan2
- AL713999.2 | c.235C>G p.L79V | Missense Mutation (SNP) | VAF 13/69 reads (19%) | catalogued as rs779612494, COSV55278763; called by muse, mutect2, varscan2
- ALAS2 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs866599436, COSV58190019; called by muse, mutect2, varscan2
- ALDH8A1 | c.439G>T p.V147F | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV55641537; called by muse, mutect2, varscan2
- AMOTL2 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 9/230 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99998121; called by muse, mutect2
- ARHGEF25 | c.1187G>A p.G396E | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV54086260; called by muse, mutect2, varscan2
- ARHGEF25 | c.1493G>C p.G498A | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.93); PolyPhen benign (0.015); catalogued as rs1228199341, COSV54086275; called by muse, mutect2, varscan2
- ATCAY | c.232T>G p.S78A | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT tolerated (0.05); PolyPhen benign (0.426); catalogued as COSV56655628; called by muse, mutect2, varscan2
- C15orf48 | c.220G>C p.E74Q | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100721085; called by muse, mutect2
- CCDC88A | c.1634_1635del p.L545Qfs*9 | Frame Shift Del (DEL) | VAF 69/243 reads (28%) | catalogued as COSV55060995; called by mutect2, pindel, varscan2
- CNOT1 | c.811G>C p.E271Q | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.08); catalogued as COSV57769865; called by muse, mutect2, varscan2
- CNTN3 | c.1982C>A p.T661N | Missense Mutation (SNP) | VAF 10/292 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99724063; called by muse, mutect2
- COL6A3 | c.5014G>C p.D1672H | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as rs1337858284, COSV55087954; called by muse, mutect2, varscan2
- DGKI | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 82/234 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55943320, COSV55947974; called by muse, mutect2, varscan2
- DHRS4L2 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 64/388 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100632639, COSV58729305; called by muse, mutect2, varscan2
- DHX30 | c.2941C>T p.Q981* (on ENST00000445061 / NM_138615.3; = p.Q942* on NM_014966.3) | Nonsense Mutation (SNP) | VAF 27/161 reads (17%) | catalogued as COSV53137172; called by muse, mutect2, varscan2
- DSCC1 | c.784G>C p.E262Q | Missense Mutation (SNP) | VAF 27/212 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.021); catalogued as COSV100558303; called by muse, mutect2, varscan2
- ENPEP | c.2314C>A p.L772I | Missense Mutation (SNP) | VAF 12/289 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as COSV99487452; called by muse, mutect2
- ERBB3 | c.3782A>C p.E1261A | Missense Mutation (SNP) | VAF 84/383 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.714); catalogued as COSV99916569; called by mutect2, varscan2
- FAT1 | c.9619C>G p.P3207A | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV71673606; called by muse, mutect2, varscan2
- FGD3 | c.531C>A p.H177Q | Missense Mutation (SNP) | VAF 71/178 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV61597070; called by muse, mutect2, varscan2
- FOXN1 | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 35/204 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as rs561636659, COSV56881624; called by muse, mutect2, varscan2
- GBP6 | c.1768A>G p.T590A | Missense Mutation (SNP) | VAF 60/240 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV65011373; called by muse, mutect2, varscan2
- GPC6 | c.286A>G p.T96A | Missense Mutation (SNP) | VAF 89/519 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1225825411, COSV65509395; called by muse, mutect2, varscan2
- HCCS | c.14C>A p.P5Q | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.03); catalogued as COSV100335660; called by muse, mutect2
- HEPHL1 | c.2875G>A p.D959N | Missense Mutation (SNP) | VAF 23/476 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV100243826; called by muse, mutect2
- HMCN1 | c.2377C>T p.P793S | Missense Mutation (SNP) | VAF 70/411 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54897093; called by muse, mutect2, varscan2
- KHDC3L | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as COSV64869115; called by muse, mutect2, varscan2
- LHX9 | c.370T>C p.Y124H | Missense Mutation (SNP) | VAF 54/288 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61328407; called by muse, mutect2, varscan2
- LMTK2 | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV51994963; called by muse, varscan2
- MAGI3 | c.3941G>A p.R1314Q | Missense Mutation (SNP) | VAF 77/367 reads (21%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as rs573108619, COSV56834262; called by muse, mutect2, varscan2
- MARK3 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 11/284 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99358142; called by muse, mutect2
- MC4R | c.802T>G p.Y268D | Missense Mutation (SNP) | VAF 81/258 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV55351943; called by muse, mutect2, varscan2
- MORN1 | c.721C>T p.Q241* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as rs1272862558, COSV66002909; called by muse, mutect2, varscan2
- MYO7A | c.1697T>C p.L566P | Missense Mutation (SNP) | VAF 13/289 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101289101; called by muse, mutect2
- NPR3 | c.741C>G p.I247M | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as rs753725976, COSV54083925, COSV54087160; called by muse, mutect2, varscan2
- OR10G7 | c.254C>G p.S85C | Missense Mutation (SNP) | VAF 104/316 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV57866895, COSV57867840; called by muse, mutect2, varscan2
- OXNAD1 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV53266592; called by muse, mutect2, varscan2
- PGBD5 | c.287C>T p.T96M (on ENST00000525115; = p.T165M on NM_001258311.2) | Missense Mutation (SNP) | VAF 27/199 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs534656022, COSV58411437; called by muse, mutect2, varscan2
- PIP4P2 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 10/305 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV99575273; called by muse, mutect2
- PKP4 | c.2645G>A p.R882K | Missense Mutation (SNP) | VAF 24/449 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV100733814; called by muse, mutect2
- PMEPA1 | c.624dup p.S209Qfs*3 | Frame Shift Ins (INS) | VAF 12/100 reads (12%) | catalogued as rs751873496; called by mutect2, varscan2
- POGLUT3 | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.135); catalogued as COSV100052615; called by muse, mutect2
- PTPRT | c.218C>G p.S73C | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61978387, COSV62011279, COSV62033916; called by muse, mutect2, varscan2
- RAPGEF1 | c.1582T>G p.F528V | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.114); catalogued as COSV64699252; called by muse, mutect2, varscan2
- RBBP6 | c.457G>C p.G153R | Missense Mutation (SNP) | VAF 65/393 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60504798; called by muse, mutect2, varscan2
- RFX7 | c.2834C>G p.S945* (on ENST00000559447 / NM_001368074.1; = p.S1042* on NM_022841.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 54/182 reads (30%) | catalogued as COSV57962872; called by muse, mutect2, varscan2
- RYR2 | c.11449C>T p.L3817F | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63682751; called by muse, mutect2, varscan2
- SEC23A | c.1330T>A p.C444S | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56973535; called by muse, mutect2, varscan2
- SERPINC1 | c.486_487del p.Y163Sfs*25 | Frame Shift Del (DEL) | VAF 60/369 reads (16%) | catalogued as rs483352850; called by pindel, varscan2
- SLC6A17 | c.1519G>A p.V507M | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as rs1164934275, COSV58992846; called by muse, mutect2, varscan2
- SSH1 | c.2216G>T p.S739I | Missense Mutation (SNP) | VAF 5/102 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.454); catalogued as COSV100425453; called by muse, mutect2
- ST18 | c.716A>C p.E239A | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as COSV52492821; called by muse, mutect2, varscan2
- STAM | c.98G>A p.C33Y | Missense Mutation (SNP) | VAF 122/465 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66325279; called by muse, mutect2, varscan2
- SYAP1 | c.910G>C p.E304Q | Missense Mutation (SNP) | VAF 53/263 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV66467949; called by muse, mutect2, varscan2
- TBC1D22A | c.1192C>T p.R398W | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1485808665, COSV61438436; called by muse, mutect2, varscan2
- TCF4 | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.905); catalogued as COSV61894052; called by muse, mutect2
- TEX55 | c.782G>A p.R261K | Missense Mutation (SNP) | VAF 34/332 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99817468; called by muse, mutect2
- TMEM163 | c.301G>C p.A101P | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.919); catalogued as COSV56106266; called by muse, mutect2, varscan2
- TMTC4 | c.1322T>C p.L441P (on ENST00000376234 / NM_001350577.2; = p.L460P on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/307 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs779577700, COSV100168618; called by muse, mutect2, varscan2
- TOMM22 | c.365G>A p.G122E | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs890390089, COSV53265565; called by muse, mutect2, varscan2
- TRIM55 | c.1007A>C p.E336A | Missense Mutation (SNP) | VAF 81/184 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV52545947; called by muse, mutect2
- USP21 | c.1054G>T p.D352Y | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV57088445; called by muse, mutect2, varscan2
- WDCP | c.1261C>T p.Q421* | Nonsense Mutation (SNP) | VAF 73/369 reads (20%) | catalogued as COSV54592212; called by muse, mutect2, varscan2
- WDR26 | c.1567G>C p.D523H (on ENST00000414423 / NM_001379403.1; = p.D423H on NM_025160.7) | Missense Mutation (SNP) | VAF 62/414 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as COSV54355059; called by muse, mutect2, varscan2
- ZKSCAN4 | c.1504C>G p.L502V | Missense Mutation (SNP) | VAF 91/373 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66023444; called by muse, mutect2, varscan2
- MED13L | c.750_753del p.E251Nfs*20 | Frame Shift Del (DEL) | VAF 58/326 reads (18%) | called by pindel, varscan2
- AKR1B10 | c.228C>T p.V76= | Silent (SNP) | VAF 8/186 reads (4%) | catalogued as COSV100610173; called by muse, mutect2
- CACNA1G | c.5334C>T p.G1778= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as COSV61725920; called by muse, mutect2, varscan2
- CDK12 | c.310C>A p.R104= | Silent (SNP) | VAF 302/3016 reads (10%) | catalogued as COSV101420425; called by muse, mutect2
- CR2 | c.2841G>A p.L947= | Silent (SNP) | VAF 24/98 reads (24%) | catalogued as rs760320098, COSV65507419; called by muse, mutect2, varscan2
- DHRS11 | c.666G>A p.E222= | Silent (SNP) | VAF 34/106 reads (32%) | called by muse, mutect2, varscan2
- EGFL6 | c.363C>T p.L121= | Silent (SNP) | VAF 53/254 reads (21%) | catalogued as rs781079982, COSV63060203; called by muse, mutect2, varscan2
- FN1 | c.2787G>A p.P929= | Silent (SNP) | VAF 27/118 reads (23%) | catalogued as rs375777163; called by muse, mutect2, varscan2
- GCNT3 | c.561C>T p.F187= | Silent (SNP) | VAF 84/348 reads (24%) | catalogued as COSV68532163, COSV68532640; called by muse, mutect2, varscan2
- IKBKE | c.1465C>T p.L489= | Silent (SNP) | VAF 20/122 reads (16%) | catalogued as rs782103849, COSV65625329; called by muse, mutect2, varscan2
- MACROH2A1 | c.381C>T p.I127= | Silent (SNP) | VAF 52/200 reads (26%) | catalogued as COSV56895040; called by muse, varscan2
- MGMT | c.291G>A p.L97= (on ENST00000306010; = p.L66= on NM_002412.5) | Silent (SNP) | VAF 27/124 reads (22%) | catalogued as COSV60026206; called by muse, mutect2, varscan2
- MORN1 | c.720G>T p.L240= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV66002913, COSV66003076; called by muse, mutect2, varscan2
- OR8K1 | c.570G>A p.L190= | Silent (SNP) | VAF 94/480 reads (20%) | catalogued as COSV54402331; called by muse, mutect2, varscan2
- PLCL1 | c.732G>A p.L244= | Silent (SNP) | VAF 81/371 reads (22%) | catalogued as COSV70829085; called by muse, mutect2, varscan2
- PPDPF | c.84C>T p.S28= | Silent (SNP) | VAF 23/28 reads (82%) | catalogued as COSV64547249; called by muse, mutect2, varscan2
- PSMD3 | c.324C>G p.L108= | Silent (SNP) | VAF 295/1876 reads (16%) | catalogued as COSV52857450, COSV99227840; called by muse, varscan2
- RYR2 | c.9849C>A p.I3283= | Silent (SNP) | VAF 31/203 reads (15%) | catalogued as COSV63682743; called by muse, mutect2, varscan2
- TDRD6 | c.2079G>A p.T693= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs377047426; called by muse, mutect2, varscan2
- TSPOAP1 | c.1839C>T p.I613= | Silent (SNP) | VAF 683/940 reads (73%) | catalogued as COSV52107686; called by muse, mutect2, varscan2
- TTLL11 | c.1197C>G p.P399= | Silent (SNP) | VAF 74/415 reads (18%) | catalogued as COSV58645858; called by muse, mutect2, varscan2
- USP19 | c.3312C>A p.I1104= | Silent (SNP) | VAF 23/106 reads (22%) | catalogued as COSV60045790; called by muse, mutect2, varscan2
- USP54 | c.4941T>C p.Y1647= | Silent (SNP) | VAF 48/238 reads (20%) | catalogued as rs746487888, COSV60442059; called by muse, mutect2, varscan2
- ZBTB41 | c.390C>T p.H130= | Silent (SNP) | VAF 81/398 reads (20%) | catalogued as rs969657056, COSV66359089; called by muse, mutect2, varscan2
- AP004606.1 | chr11:133532324 T>C | 5'Flank (SNP) | VAF 9/28 reads (32%) | catalogued as COSV73220045; called by muse, mutect2, varscan2
- ARIH2 | chr3:48918570 C>T | 5'Flank (SNP) | VAF 9/42 reads (21%) | catalogued as COSV62704591; called by muse, mutect2, varscan2
